Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040024-09A.1 (aliquot TARGET-15-SJMPAL040024-09A.1-01D) from TARGET case TARGET-15-SJMPAL040024, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (366 days).
Specimen TARGET-15-SJMPAL040024-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b26312b3-40a8-4d79-b82b-c0b6e02b735c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040024-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040024-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fc550de-f219-4ca0-bcff-e7aa7ce4b541

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1280228461; called by muse, mutect2
- DCAF4L2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100150917, COSV60481430; called by muse, mutect2
- MICAL2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396469560, COSV56327169; called by muse, mutect2
- SAGE1 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61012185; called by muse, mutect2
- CDKL1 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- SEC23IP | c.1739C>A p.A580D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SRCAP | c.6889del p.R2297Gfs*10 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | called by mutect2, pindel, varscan2
- ILF3 | c.1918C>A p.R640= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
